Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A7CH, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A7CH-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT - CONSULT

Patient Name:

Address:

Gender:

DOB:

F

(Age:)

Service:

Location:

MRN :

Hospital #:

Patient Type:

Accession #:

Received:

Reported:

Physician(s):

DIAGNOSIS

UTERUS, CERVIX, BIOPSY

- SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED, INVASIVE

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

M.D.

Report Electronically Reviewed and Signed Out By M.D.

Microscopic Description and Comment

Microscopic examination substantiates the above cited diagnosis.

History

(Not Provided)

Material(s) Received

Received is one slide labeled , accompanied by a corresponding pathology report. The material originates from . The original material is returned.

ICD-O-3
Cervix, squamous cell NOS
Site Cervix NOS
8070/3
053.9

8/27/13

Source: NCI Genomic Data Commons file 71211751-2e0d-490c-bb10-bd8459792670 (TCGA-C5-A7CH.68C37151-5277-4370-BEA9-5DBD6429E06F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).